Somatic mutation profile of tumor specimen TARGET-10-PAPCRJ-09A (aliquot TARGET-10-PAPCRJ-09A-01D) from TARGET case TARGET-10-PAPCRJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,032 days).
Specimen TARGET-10-PAPCRJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deaa1331-17cb-4315-8772-7415f5fcf93e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCRJ-10A (Blood Derived Normal), aliquot TARGET-10-PAPCRJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57a0cdc1-89cc-4f96-8906-05fc046e1aa2

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP6 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1377601500, COSV57291698; called by muse, mutect2, varscan2
- DNAH10 | c.478G>A p.V160M (on ENST00000409039; = p.V99M on NM_207437.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs539668219, COSV68999289; called by muse, mutect2, varscan2
- GFRA3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1313406084; called by muse, mutect2, varscan2
- GPA33 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs774631325, COSV63300052; called by muse, mutect2, varscan2
- MYH6 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs533942127, COSV62448343, COSV62452078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NWD2 | c.4931C>T p.T1644M | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs750496899, COSV58752394; called by muse, mutect2, varscan2
- TET2 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54410503; called by muse, mutect2
- TSBP1 | c.883G>T p.A295S (on ENST00000617061; = p.A298S on NM_006781.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1225351124, COSV66659137; called by mutect2, varscan2
- UPF2 | c.2233G>T p.V745F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100707485; called by muse, mutect2, varscan2
- DDX19A | c.275C>A p.S92* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- DEGS1 | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- IGSF6 | c.600_602dup p.R201dup | In Frame Ins (INS) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- NEFL | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.02); called by muse, varscan2
- NRM | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR6T1 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2
- TET1 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- UBN1 | c.2657C>A p.P886Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HARS2 | c.1107C>A p.G369= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, varscan2
- HIKESHI | c.219C>A p.V73= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- MORN2 | c.87T>A p.T29= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
